Somatic mutation profile of tumor specimen TCGA-60-2710-01A (aliquot TCGA-60-2710-01A-01D-1522-08) from TCGA case TCGA-60-2710, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.5 years (24,669 days).
Specimen TCGA-60-2710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f8b08b9-1a64-4648-93e2-41fc081f62ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2710-11A (Solid Tissue Normal), aliquot TCGA-60-2710-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4740a077-6ace-42d6-b227-02ce3f0feefc

The open-access MAF lists 223 somatic variants for this specimen: 179 protein-altering or splice-affecting, 42 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 42, Nonsense Mutation 10, Frame Shift Del 6, Splice Site 5, Frame Shift Ins 3, Intron 2, In Frame Del 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.870G>C p.W290C | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121918499, CM970527, CM970528, COSV60643917; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV50260643, COSV50262012; called by muse, mutect2, varscan2
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 22/63 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.3085G>A p.A1029T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs942306533, COSV60695342; called by muse, mutect2, varscan2
- ABCD1 | c.838C>A p.R280S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193922098, CM021052, COSV54388375; called by muse, mutect2, varscan2
- ABCD1 | c.1526A>G p.N509S | Missense Mutation (SNP) | VAF 47/251 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs782158792, CM044845, COSV54388211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD10 | c.332A>T p.D111V | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56326578; called by muse, mutect2, varscan2
- ABHD4 | c.639G>A p.W213* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | catalogued as COSV53530947; called by muse, mutect2, varscan2
- ADAMTS7 | c.5056C>T p.R1686C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs367561272; called by muse, mutect2, varscan2
- ADGRB1 | c.1490C>A p.P497H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60104227; called by muse, mutect2
- ADHFE1 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.371); catalogued as COSV52559855; called by muse, mutect2, varscan2
- AKAP17A | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 97/354 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs756733838, COSV58312497; called by muse, mutect2, varscan2
- ALG13 | c.3170C>A p.S1057Y | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV52646117; called by muse, mutect2, varscan2
- AMBRA1 | c.3749C>A p.S1250Y (on ENST00000458649 / NM_001367468.1; = p.S1160Y on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV54064076; called by muse, mutect2, varscan2
- AMHR2 | c.1390C>G p.P464A | Missense Mutation (SNP) | VAF 92/311 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57687353; called by muse, mutect2, varscan2
- AMMECR1 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 84/357 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.326); catalogued as COSV53321132; called by muse, mutect2, varscan2
- ARHGEF10L | c.943-1G>T p.X315_splice | Splice Site (SNP) | VAF 44/248 reads (18%) | catalogued as COSV51442740; called by muse, mutect2, varscan2
- ARMCX2 | c.325A>T p.S109C | Missense Mutation (SNP) | VAF 105/227 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.171); catalogued as COSV57531345; called by muse, mutect2, varscan2
- ASIC2 | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV63331474; called by muse, mutect2, varscan2
- ASIC3 | c.216C>A p.H72Q | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52511692; called by muse, mutect2, varscan2
- ATP10D | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs561130132, COSV56703624; called by muse, mutect2, varscan2
- ATP13A5 | c.2374T>C p.C792R | Missense Mutation (SNP) | VAF 37/352 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs760725199, COSV60871826; called by muse, mutect2, varscan2
- BCAP31 | c.94T>C p.W32R | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54383685; called by muse, varscan2
- BCL9L | c.1906G>A p.G636S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1352185829, COSV52690156; called by muse, mutect2, varscan2
- BORA | c.1669G>A p.E557K (on ENST00000613797; = p.E482K on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 161/325 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64696050; called by muse, mutect2, varscan2
- BRWD3 | c.1862G>T p.G621V | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as COSV64754581; called by muse, mutect2, varscan2
- BUB1 | c.1922G>T p.C641F | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57067928; called by muse, mutect2, varscan2
- C3orf38 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59629092; called by muse, mutect2, varscan2
- CA11 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV50034516; called by muse, mutect2, varscan2
- CC2D1B | c.84G>C p.M28I | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52563538; called by muse, mutect2, varscan2
- CCDC170 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV53347482; called by muse, mutect2, varscan2
- CDC7 | c.1724G>T p.*575Lext*1 | Nonstop Mutation (SNP) | VAF 30/148 reads (20%) | catalogued as COSV52313164; called by muse, mutect2, varscan2
- CDKL5 | c.3036G>T p.Q1012H | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV66107717; called by muse, mutect2, varscan2
- CDKL5 | c.3037G>T p.V1013L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV66107723; called by muse, mutect2, varscan2
- CELF4 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV58467729; called by muse, mutect2, varscan2
- CEP152 | c.1543A>G p.K515E | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV57866231; called by muse, mutect2, varscan2
- CHGB | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs368972632; called by muse, mutect2, varscan2
- CLINT1 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.31); catalogued as COSV51630033; called by muse, mutect2, varscan2
- COL1A1 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV56810076; called by muse, mutect2, varscan2
- COL4A1 | c.3685C>A p.H1229N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.835); catalogued as COSV65432746; called by muse, mutect2, varscan2
- COL4A2 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64635152; called by muse, mutect2, varscan2
- COL4A4 | c.4325G>T p.G1442V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61637218; called by muse, mutect2, varscan2
- COLEC11 | c.83C>A p.A28D | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.113); catalogued as COSV52598439; called by muse, mutect2, varscan2
- CPXCR1 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 35/159 reads (22%) | catalogued as rs922613625, COSV52164922; called by muse, mutect2, varscan2
- CRB1 | c.931C>A p.H311N | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.799); catalogued as COSV66350228; called by muse, mutect2, varscan2
- CSMD3 | c.3281C>A p.T1094K (on ENST00000297405 / NM_001363185.1; = p.T990K on NM_052900.3) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV52158763; called by muse, mutect2, varscan2
- CYB5R4 | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774440809, COSV63752629; called by muse, mutect2, varscan2
- DAB1 | c.1162C>T p.P388S (on ENST00000371231; = p.P355S on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as COSV100976722, COSV64691995; called by muse, mutect2, varscan2
- DMRT1 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs766842219, COSV66524916; called by muse, varscan2
- EEF1AKNMT | c.597G>T p.Q199H (on ENST00000361735 / NM_015935.5; = p.Q113H on NM_014955.3) | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.106); catalogued as COSV62283939; called by muse, mutect2, varscan2
- EIF4E3 | c.352G>T p.E118* (on ENST00000425534 / NM_001134651.2; = p.E12* on NM_173359.5) | Nonsense Mutation (SNP) | VAF 71/123 reads (58%) | catalogued as COSV55207327; called by muse, mutect2, varscan2
- EPHA3 | c.2275G>T p.V759L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs146856660, COSV60730088; called by muse, mutect2, varscan2
- EPHA6 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 94/667 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs780254423, COSV67598252; called by muse, mutect2, varscan2
- EVC2 | c.3176A>G p.N1059S | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60405192; called by muse, mutect2, varscan2
- F7 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60648629; called by muse, mutect2, varscan2
- FAM120B | c.1719C>G p.D573E | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV53009269; called by muse, mutect2, varscan2
- FBXL7 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61654872; called by muse, mutect2, varscan2
- FILIP1L | c.2247dup p.L750Tfs*16 (on ENST00000354552 / NM_182909.3; = p.L510Tfs*16 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 66/600 reads (11%) | catalogued as rs1433753279; called by mutect2, varscan2
- FSTL5 | c.767G>T p.S256I | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV60238057; called by muse, mutect2, varscan2
- GBA | c.205A>C p.T69P | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59171242; called by muse, mutect2, varscan2
- GDAP2 | c.1276T>G p.F426V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV65613591; called by muse, mutect2, varscan2
- GPM6A | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.994); catalogued as COSV54531787, COSV54565099; called by muse, mutect2, varscan2
- HDC | c.848G>A p.C283Y | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51085364; called by muse, mutect2, varscan2
- HEPH | c.718C>A p.H240N (on ENST00000343002; = p.H294N on NM_138737.5) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs1456888736, COSV57973476; called by muse, mutect2, varscan2
- HIVEP1 | c.6682A>T p.T2228S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as COSV65105478; called by muse, mutect2, varscan2
- HMMR | c.1987G>T p.A663S | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.327); catalogued as COSV62375645; called by muse, mutect2, varscan2
- HOXA4 | c.69C>A p.Y23* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV57829499; called by muse, varscan2
- HSCB | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as COSV53263569; called by muse, mutect2, varscan2
- HUWE1 | c.10715T>A p.V3572E | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.035); catalogued as COSV53367705; called by muse, mutect2, varscan2
- IFFO1 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60739674; called by muse, mutect2, varscan2
- IGSF1 | c.629G>A p.W210* | Nonsense Mutation (SNP) | VAF 46/223 reads (21%) | catalogued as COSV63841040; called by muse, mutect2, varscan2
- IL1RAPL1 | c.978A>C p.E326D | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.057); catalogued as COSV56310003; called by muse, mutect2, varscan2
- IL2RG | c.854+2T>G p.X285_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as CS011541, COSV52150565; called by muse, mutect2, varscan2
- IMPACT | c.41A>C p.E14A | Missense Mutation (SNP) | VAF 99/298 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV52423826; called by muse, mutect2, varscan2
- IMPG1 | c.553A>T p.I185F | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64055196; called by muse, mutect2, varscan2
- INTS7 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV65345698; called by muse, mutect2, varscan2
- IRAK1 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 136/326 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1186579541, COSV64113842; called by muse, mutect2, varscan2
- IRF6 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 85/241 reads (35%) | catalogued as COSV65420641; called by muse, mutect2, varscan2
- ISL1 | c.260G>C p.S87T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV57935986; called by muse, mutect2, varscan2
- JADE3 | c.822G>T p.W274C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54471584; called by muse, mutect2, varscan2
- JAG2 | c.1294T>C p.C432R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59313953; called by muse, mutect2, varscan2
- KCNMB3 | c.36T>G p.H12Q | Missense Mutation (SNP) | VAF 46/379 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV58571836; called by muse, mutect2, varscan2
- KMT2C | c.4349A>G p.D1450G | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV51516547; called by muse, mutect2, varscan2
- KRT81 | c.886T>C p.W296R | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59811728; called by muse, mutect2, varscan2
- LAMP3 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 68/884 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs150380664; called by muse, mutect2
- LCE3A | c.229G>T p.G77W | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV59551239; called by muse, mutect2, varscan2
- LHFPL5 | c.630C>A p.D210E | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV64178830; called by muse, mutect2, varscan2
- LRP1B | c.12938C>A p.P4313Q | Missense Mutation (SNP) | VAF 147/507 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV101254409, COSV67280348; called by muse, mutect2, varscan2
- LRP2 | c.4498A>G p.R1500G | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as rs777314724, COSV55579530; called by muse, mutect2, varscan2
- LRRK2 | c.3943G>A p.A1315T | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV54175503; called by muse, mutect2, varscan2
- MAGI2 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV62687638; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV61010785; called by muse, mutect2, varscan2
- MC3R | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV54765293; called by muse, mutect2, varscan2
- MED12 | c.4120-1G>T p.X1374_splice | Splice Site (SNP) | VAF 34/154 reads (22%) | catalogued as COSV61359293; called by muse, mutect2, varscan2
- MED12 | c.4120G>T p.E1374* | Nonsense Mutation (SNP) | VAF 33/150 reads (22%) | catalogued as COSV61359301; called by muse, mutect2, varscan2
- MEF2D | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 66/237 reads (28%) | catalogued as COSV61730570; called by muse, mutect2, varscan2
- MEGF6 | c.267-1G>T p.X89_splice | Splice Site (SNP) | VAF 27/97 reads (28%) | catalogued as COSV62994887; called by muse, mutect2
- MLKL | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); catalogued as COSV58205809, COSV58206891; called by muse, mutect2
- MTHFD1L | c.2029G>C p.V677L | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV66227845; called by muse, mutect2, varscan2
- MUC6 | c.2568G>A p.W856* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs769561663, COSV70151573; called by muse, mutect2
- MYB | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57202787; called by muse, mutect2, varscan2
- MYO15A | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.602); catalogued as rs748573149, COSV52768585; called by muse, mutect2, varscan2
- NBAS | c.2016C>T p.S672= | Splice Region (SNP) | VAF 20/72 reads (28%) | catalogued as COSV55741477; called by muse, mutect2, varscan2
- NCK1 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 118/665 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs773408330, COSV56639032; called by muse, mutect2, varscan2
- NEUROD6 | c.640C>G p.P214A | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.283); catalogued as COSV51773785; called by muse, mutect2, varscan2
- NHS | c.3274C>T p.H1092Y | Missense Mutation (SNP) | VAF 116/400 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV66274792; called by muse, mutect2, varscan2
- NKAPL | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV59199711; called by muse, mutect2, varscan2
- NLRP13 | c.269A>G p.Q90R | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.182); catalogued as COSV61624525; called by muse, mutect2
- NOS3 | c.1225A>G p.S409G | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52492188, COSV52497030; called by muse, mutect2, varscan2
- NUP210L | c.2850+2T>A p.X950_splice | Splice Site (SNP) | VAF 76/230 reads (33%) | catalogued as COSV55159019; called by muse, mutect2, varscan2
- OCRL | c.2329C>A p.P777T | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.516); catalogued as COSV63982233; called by muse, mutect2, varscan2
- OR13G1 | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV62945416; called by muse, mutect2, varscan2
- OTOL1 | c.1418C>A p.S473Y | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.017); catalogued as COSV60008863; called by muse, mutect2, varscan2
- PAOX | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs1472318687, COSV53371964; called by muse, mutect2, varscan2
- PCK1 | c.865G>T p.G289W | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60130976, COSV60131680; called by muse, mutect2, varscan2
- PKD1 | c.8865C>G p.H2955Q | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs1199361266, COSV51927746; called by muse, mutect2
- PKDREJ | c.3967C>T p.H1323Y | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV53554172; called by muse, mutect2, varscan2
- PLCB2 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV53039081; called by muse, mutect2, varscan2
- PPM1B | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56770369; called by muse, mutect2, varscan2
- PPP1R3F | c.1772A>C p.E591A | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.378); catalogued as COSV50020857; called by muse, mutect2, varscan2
- RBMS2 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1050943172; called by muse, mutect2
- RERE | c.386A>T p.D129V | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61938407, COSV61952139; called by muse, mutect2, varscan2
- RHBDL2 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56710235; called by muse, mutect2, varscan2
- RHOH | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV67807378; called by muse, mutect2, varscan2
- RNF20 | c.1943A>T p.D648V | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66662532; called by muse, mutect2, varscan2
- RNF213 | c.2510A>G p.E837G | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV60631610; called by muse, mutect2, varscan2
- RP1 | c.1325C>A p.A442E | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs755794081, COSV55129224; called by muse, mutect2, varscan2
- RPS6KC1 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 96/315 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65303424; called by muse, mutect2, varscan2
- RTL9 | c.979G>C p.V327L | Missense Mutation (SNP) | VAF 224/920 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV71826535; called by muse, mutect2, varscan2
- RTTN | c.2197C>G p.L733V | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776126193, COSV55341618; called by muse, mutect2, varscan2
- RUBCNL | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV59795377; called by muse, mutect2
- RXFP1 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV57058080; called by muse, mutect2, varscan2
- SELENOP | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV62794386; called by muse, mutect2, varscan2
- SEMA4C | c.2330A>T p.H777L | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV59692701; called by muse, mutect2, varscan2
- SERINC4 | c.893T>A p.I298N | Missense Mutation (SNP) | VAF 80/376 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV51052203; called by muse, mutect2, varscan2
- SERPINB11 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as COSV66958006; called by muse, mutect2, varscan2
- SGSM1 | c.1652T>A p.F551Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV68514405; called by muse, mutect2, varscan2
- SLC10A7 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV53891991; called by muse, mutect2, varscan2
- SLC35F1 | c.707G>T p.W236L | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV64511483; called by muse, mutect2, varscan2
- SLC9A6 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV65789256; called by muse, mutect2, varscan2
- SNX32 | c.1117A>C p.N373H | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57450763; called by muse, mutect2, varscan2
- SON | c.4067C>T p.A1356V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV51671712; called by muse, mutect2, varscan2
- SUCLA2 | c.306A>T p.L102F | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV66223304; called by muse, mutect2
- SUN3 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV52054910; called by muse, mutect2, varscan2
- TBXT | c.1045A>T p.S349C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV51620643; called by muse, mutect2, varscan2
- TMEM101 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780876294, COSV52814337; called by muse, mutect2, varscan2
- TMEM132D | c.1522T>C p.Y508H | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV67163137; called by muse, mutect2, varscan2
- TNKS1BP1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV64103085; called by muse, mutect2, varscan2
- TRPM8 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV61224631; called by muse, mutect2, varscan2
- TRPV5 | c.1438A>G p.I480V | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.279); catalogued as rs1224508560, COSV54690896; called by muse, mutect2, varscan2
- TTC21A | c.1612C>T p.H538Y | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV57189898; called by muse, mutect2, varscan2
- TTC7A | c.2451G>C p.Q817H | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.214); catalogued as COSV55416419; called by muse, mutect2, varscan2
- TUBB4A | c.88A>T p.I30F | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV51168574; called by muse, mutect2, varscan2
- TYK2 | c.3309C>A p.S1103R | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53385889; called by muse, varscan2
- TYK2 | c.2941G>A p.V981M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV99314122; called by muse, varscan2
- VPS13C | c.2487G>T p.M829I (on ENST00000644861 / NM_020821.3; = p.M786I on NM_017684.5) | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51429490; called by muse, mutect2, varscan2
- VPS13D | c.9437G>T p.C3146F | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as COSV50621385; called by muse, mutect2, varscan2
- WNK3 | c.1463T>C p.V488A | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63616372; called by muse, mutect2, varscan2
- WNT2B | c.802C>T p.R268C (on ENST00000369684 / NM_024494.3; = p.R249C on NM_004185.4) | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs761702933, COSV56674751, COSV56676043; called by muse, mutect2, varscan2
- WWTR1 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs762511917, COSV62293669; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1465G>C p.V489L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV54302284; called by muse, mutect2, varscan2
- ZNF101 | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV58910183; called by muse, mutect2, varscan2
- ZNF460 | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as COSV64416686; called by muse, mutect2, varscan2
- ZNF543 | c.686G>T p.C229F | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58629606; called by muse, mutect2, varscan2
- ZNF57 | c.621T>A p.H207Q | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV60984992; called by muse, mutect2, varscan2
- ZNF761 | c.1288A>T p.K430* | Nonsense Mutation (SNP) | VAF 22/194 reads (11%) | catalogued as COSV61889695; called by muse, mutect2, varscan2
- ZNF804A | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1253639368, COSV56440021, COSV56475982; called by muse, mutect2, varscan2
- ZNF804A | c.2966C>A p.T989N | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs764514125, COSV56474023; called by muse, mutect2, varscan2
- AGAP4 | c.160G>T p.V54L | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CAGE1 | c.716dup p.N239Kfs*7 (on ENST00000512086; = p.N103Kfs*7 on NM_205864.3) | Frame Shift Ins (INS) | VAF 65/260 reads (25%) | called by mutect2, pindel, varscan2
- CD276 | c.249_271del p.D84Pfs*82 | Frame Shift Del (DEL) | VAF 11/110 reads (10%) | called by mutect2, pindel
- CHD7 | c.1412dup p.L471Ffs*104 | Frame Shift Ins (INS) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- NEGR1 | c.369_371del p.Q123del | In Frame Del (DEL) | VAF 26/95 reads (27%) | called by mutect2, pindel, varscan2
- PDE4DIP | c.3214G>A p.E1072K | Missense Mutation (SNP) | VAF 33/498 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2
- POLQ | c.2138del p.M713Rfs*14 | Frame Shift Del (DEL) | VAF 89/564 reads (16%) | called by mutect2, pindel, varscan2
- SYNPO2 | c.3300del p.I1101Ffs*22 | Frame Shift Del (DEL) | VAF 40/195 reads (21%) | called by mutect2, pindel, varscan2
- TIMM22 | c.236del p.G79Efs*5 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- TRIM48 | c.589del p.V197Cfs*9 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- TYK2 | c.3315del p.T1106Rfs*7 | Frame Shift Del (DEL) | VAF 46/237 reads (19%) | called by pindel, varscan2
- ADAM2 | c.1893G>A p.K631= | Silent (SNP) | VAF 89/275 reads (32%) | catalogued as COSV55869158; called by muse, mutect2, varscan2
- AFTPH | c.819G>T p.L273= | Silent (SNP) | VAF 52/133 reads (39%) | catalogued as COSV53216154, COSV53222778; called by muse, mutect2, varscan2
- AHNAK | c.14358C>G p.P4786= | Silent (SNP) | VAF 117/483 reads (24%) | catalogued as COSV57235289; called by muse, mutect2, varscan2
- ALPK3 | c.2832G>T p.G944= | Silent (SNP) | VAF 32/248 reads (13%) | catalogued as COSV51941734; called by muse, mutect2, varscan2
- CCL20 | c.51A>C p.L17= | Silent (SNP) | VAF 77/251 reads (31%) | catalogued as COSV62591827; called by muse, mutect2, varscan2
- CEACAM5 | c.879T>C p.N293= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as COSV55756039; called by muse, mutect2, varscan2
- COL4A5 | c.3165C>T p.S1055= | Silent (SNP) | VAF 39/291 reads (13%) | catalogued as COSV60373006, COSV60374636; called by muse, mutect2, varscan2
- CRISP3 | c.765C>T p.T255= (on ENST00000371159 / NM_001368123.1; = p.T237= on NM_006061.4) | Silent (SNP) | VAF 34/217 reads (16%) | catalogued as COSV53823598; called by muse, mutect2, varscan2
- CWF19L2 | c.1464G>T p.L488= | Silent (SNP) | VAF 48/167 reads (29%) | catalogued as COSV56508281, COSV56521931; called by muse, mutect2, varscan2
- DCC | c.1671A>T p.P557= | Silent (SNP) | VAF 98/346 reads (28%) | catalogued as COSV59144685; called by muse, mutect2, varscan2
- ERBB4 | c.3087C>T p.N1029= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV61531510; called by muse, mutect2, varscan2
- FAT4 | c.594G>T p.A198= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV67891190, COSV67901864; called by muse, mutect2, varscan2
- FBXO40 | c.24G>T p.P8= | Silent (SNP) | VAF 144/390 reads (37%) | catalogued as COSV57522997, COSV57528285; called by muse, mutect2, varscan2
- FIGN | c.1152C>T p.S384= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as rs762282252, COSV60772814; called by muse, mutect2, varscan2
- GRIN2B | c.3825C>T p.N1275= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as rs200571186, COSV74204684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H1-2 | c.441G>A p.P147= | Silent (SNP) | VAF 64/206 reads (31%) | catalogued as COSV59192137, COSV59193598; called by muse, mutect2, varscan2
- HLA-DMB | c.366C>A p.T122= | Silent (SNP) | VAF 60/210 reads (29%) | catalogued as COSV66870651, COSV66870991; called by muse, mutect2, varscan2
- HMBOX1 | c.390A>G p.G130= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV55072903; called by muse, mutect2, varscan2
- HUWE1 | c.6429G>T p.G2143= | Silent (SNP) | VAF 41/203 reads (20%) | catalogued as COSV53367724; called by muse, mutect2, varscan2
- IGHV3-30 | c.132T>C p.S44= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as rs760862789; called by muse, mutect2, varscan2
- IMPG2 | c.2832G>T p.T944= | Silent (SNP) | VAF 176/300 reads (59%) | catalogued as COSV51975531; called by muse, mutect2, varscan2
- ISL1 | c.189G>A p.G63= | Silent (SNP) | VAF 78/335 reads (23%) | catalogued as rs777485181, COSV57936215; called by muse, mutect2, varscan2
- LRRC30 | c.363C>G p.V121= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV67302410; called by muse, mutect2, varscan2
- NOP14 | c.1935G>A p.S645= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs778767912, COSV58628238; called by muse, mutect2, varscan2
- OR5T2 | c.174C>T p.D58= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs769262623, COSV100507125, COSV57591608; called by muse, mutect2, varscan2
- PUS1 | c.1269C>T p.D423= | Silent (SNP) | VAF 36/168 reads (21%) | catalogued as rs531516145, COSV59036898; called by muse, mutect2, varscan2
- SEMA4C | c.2331C>T p.H777= | Silent (SNP) | VAF 54/228 reads (24%) | catalogued as rs200526785, COSV59692693; called by muse, mutect2, varscan2
- SEMG1 | c.390T>C p.H130= | Silent (SNP) | VAF 32/123 reads (26%) | catalogued as rs1474784120, COSV54875015; called by muse, mutect2, varscan2
- SERPINA12 | c.78A>G p.S26= | Silent (SNP) | VAF 87/177 reads (49%) | catalogued as COSV57946550; called by muse, mutect2, varscan2
- SPATA31E1 | c.744G>A p.P248= | Silent (SNP) | VAF 36/271 reads (13%) | catalogued as rs370494405, COSV57793610, COSV57796058; called by muse, mutect2, varscan2
- SPTLC3 | c.798T>C p.G266= | Silent (SNP) | VAF 32/153 reads (21%) | catalogued as rs771123243, COSV65469325; called by muse, mutect2, varscan2
- SZT2 | c.10095G>A p.L3365= (on ENST00000634258 / NM_001365999.1; = p.L3308= on NM_015284.4) | Silent (SNP) | VAF 7/145 reads (5%) | catalogued as COSV65095624; called by muse, mutect2
- TENM1 | c.3780C>A p.V1260= | Silent (SNP) | VAF 170/411 reads (41%) | catalogued as COSV64445359; called by muse, mutect2, varscan2
- TENM3 | c.3435C>A p.V1145= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV69312553, COSV69322301; called by muse, mutect2, varscan2
- TERT | c.2160C>A p.I720= | Silent (SNP) | VAF 114/477 reads (24%) | catalogued as COSV57245576; called by muse, mutect2, varscan2
- TMPRSS15 | c.600T>A p.A200= | Silent (SNP) | VAF 46/133 reads (35%) | catalogued as COSV53051458; called by muse, mutect2, varscan2
- TRPC5 | c.1923T>C p.F641= | Silent (SNP) | VAF 52/274 reads (19%) | catalogued as COSV53305115; called by muse, mutect2, varscan2
- UVSSA | c.2091C>T p.H697= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs529975173, COSV66231168; called by muse, mutect2, varscan2
- ZNF442 | c.840T>C p.Y280= | Silent (SNP) | VAF 147/404 reads (36%) | catalogued as COSV54423726; called by muse, mutect2, varscan2
- ZNF676 | c.1659T>A p.T553= (on ENST00000650058; = p.T521= on NM_001001411.3) | Silent (SNP) | VAF 65/194 reads (34%) | catalogued as COSV68095200; called by muse, mutect2, varscan2
- ZNF91 | c.1572C>T p.G524= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as COSV56095354; called by muse, mutect2, varscan2
- ZNF93 | c.1398A>T p.S466= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as rs559404029, COSV59373804; called by muse, varscan2
- H2BP2 | n.1061+501T>A | Intron (SNP) | VAF 24/66 reads (36%) | called by mutect2, varscan2
- PRB1 | c.101-542G>A | Intron (SNP) | VAF 66/214 reads (31%) | catalogued as COSV53707208; called by muse, mutect2, varscan2
